Surgical pathology report (de-identified scan), TCGA case TCGA-FC-A66V, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Asterand, specimen TCGA-FC-A66V-01A (Primary Tumor).

[page 1 of 2]
TSS Patient ID:

OpenClinica ID:

Surgical Date:

Gross Description: A. "Left pelvic node." A 3.5 x 2.0 x 0.4 cm lymph node.

B. "Right pelvic node." A 1.0 cm lymph node admixed with 1.0 cm adipose tissue.

C. "Prostate." A 52 gram, 5.0 x 4.0 x 3.8 cm prostatectomy specimen with attached seminal vesicles and an intact capsule. The prostate is inked as follows: Anterior red, right side black and left side blue. The apex is shaved, cut perpendicularly and submitted in C1 and C2. The bladder neck is shaved, cut perpendicularly and submitted in C3 and C4. The remaining prostate is serially sectioned transversely revealing a tumor in the left postero-lateral aspect from apex to base, 2.5 x 1.5 x 0.5 cm. There is also yellow orange tumor in the right postero-lateral mid to base, 2.5 x 2.5 x 1.0 cm. The right seminal vesical had questionable tumor.

D. "Prostatic apex." A 0.3 and 0.4 cm fragment.

E. "Bladder neck." A 0.7 x 0.3 x 0.2 cm fragment.

ICD-O-3
Adenocarcinoma, acinar 8140/3
Site Prostate NOS C61.9
9/24/13

Microscopic Description: Gleason score: 4 + 3 = 7

Higher tertiary pattern: Absent

Tumor quantity: 40% of prostatic tissue; maximum linear extent at least 23 mm

Prostate size: 52 gram

Location: Bilateral

Histologic type: Conventional

Therapy-related change: Absent

Extracapsular extension: Present (Bilateral base, near seminal vesicles, at least 0.5 cm extent)

Seminal vesicle invasion: Present (right side, suspicious for left side involvement)

Angiolymphatic Invasion: Present (focal)

Margins: All margins free of tumor

Lymph node (right pelvic, B): 1 lymph node free of tumor

Lymph node (left pelvic, A): 1 lymph node free of tumor

Pathologic stage: pT3b N0 Mx

Diagnosis Details: Prostate: Adenocarcinoma, acinar cell

Bladder neck: Benign smooth muscle, no prostate glands.

[page 2 of 2]
Comments: Tumor involves the right seminal vesicle, and also involves the intraprostatic portion of the left seminal vesicle. Clear involvement of the extraprostatic left seminal vesicle is not seen in these sections.

Formatted Path Reports: PROSTATE TISSUE CHECKLIST

Specimen type: Robot assisted radical prostatectomy

Tumor size: 2.3 cm

Histologic type: Acinar cell adenocarcinoma

Gleason's score: 4 + 3 = 7/10

Focality: Not specified

Laterality: Bilateral

Extraprostatic extension: Present

Lymph nodes: 0/2 positive for metastasis (Left and right pelvic 0/2)

Lymphatic invasion: Present

Venous invasion: Present

Seminal vesicle invasion: Present

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 2179f8ba-4abb-4529-abe6-d075ccb29f15 (TCGA-FC-A66V.3C1BD6CD-0915-4DEA-A013-F2DE554C267F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).